Surgical pathology report (de-identified scan), TCGA case TCGA-75-7031, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-7031-01A (Primary Tumor).

[page 1 of 6]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details

Sample Number	Sample Type
	BUFFY
	TUMOUR

[page 2 of 6]
					Histology and staging			
Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)
FF	RUL lung			processing		1	12 RESECT	RUL
FF						0	11 RESECT	RUL

[page 3 of 6]
Tumour Size (cm)	Histology	Grade/Differentiation	Pathologic al T	Pathologic al N	Clinical M	VALCSG Stage	Histology Comments	Slide URL
999.99		3 I	T2,NOS	N0	M0		Spec. #2 was rt lung, u	
999.99		3 I	T2,NOS	N0	M0			

[page 4 of 6]
pper lobectomy & wedge rt. middle lobe. Tumour #1- 1.5 cm, & #2 0.8 cm. Histologic type: Tumour 1-A

[page 5 of 6]
denoca, tumour 2- Adenoca (with features consistent with bronchioloalveolar carcinoma). Visceral pleu

[page 6 of 6]
ral involvement in tumour #2.

Source: NCI Genomic Data Commons file c76143a1-9e33-4b3c-8f9a-ca8d3f2d0dd7 (TCGA-75-7031.0F516D64-BEC9-42FF-9432-D626193C3DD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).